Somatic mutation profile of tumor specimen MP2PRT-PASMXJ-TMP1-A (aliquot MP2PRT-PASMXJ-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PASMXJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.9 years (4,350 days).
Specimen MP2PRT-PASMXJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4e49435-29f6-442f-b4ff-4dd9df2bdd09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASMXJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASMXJ-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44998f20-389c-4a0a-b8d9-5cc77a2adb56

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RNF165 | c.747G>T p.L249F | Missense Mutation (SNP) | VAF 38/334 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV99491867; called by muse, mutect2, varscan2
- CACNB1 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 73/475 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714682 TCT>GAACCAAGGCGCTTGCGG | Missense Mutation (INS) | VAF 42/174 reads (24%) | called by pindel, varscan2*
- SYT16 | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ZNF787 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2
